Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RC-01A (Primary Tumor).

[page 1 of 2]
IHPAA Discrepancy		☒

MR#: [REDACTED]

Surg Path Report

Sex: F

ICD-0-3

carcinoma, squamous cell, NOS 8070/3

Site: cervix, NOS C53.9 lw 9/8/11

ACCESSION:

SOURCE OF TISSUE:

1. RIGHT PELVIC LYMPH NODE (1FS) 2. RIGHT PELVIC LYMPH NODES 3. RADICAL HYSTERECTOMY SPECIMEN 4. LEFT PELVIC LYMPH NODES

GROSS:

Specimen "No. 1" labeled "Right Pelvic Lymph Node" consists of one 1.5x0.5x0.5-cm tan portion of tissue. Half is submitted for frozen section as "1FS". All tissue is submitted as "1FS+1".

Specimen "No. 2" labeled "Right Pelvic Lymph Nodes" consists of fragments of fibrofatty tissue measuring in aggregate 4x3x1 cm. The specimen is submitted as: "2A", one possible lymph node; "2B", one possible lymph node; "2C", remainder of adipose.

Specimen "No. 3" labeled "Radical Hysterectomy Specimen" consists of one uterus without bilateral uterine tubes or ovaries, weighing 168 g and measuring from fundus to cervix 8 cm, from cornu to cornu 5 cm, anterior to posterior is 4 cm. The cervix is complete and received with vaginal cuff. The cervical diameter is 2.5 cm, os is patent. An exophytic mass is identified on the anterior and posterior aspect of cervix extending from the 6 o'clock position to 12 o'clock position and encompasses approximately one half of exterior surface of cervix and extends into the endocervical canal. The entire mass measures 3x2.8x2 cm. The endometrial cavity reveals a spongy endometrium. Myometrium is homogenous and firm. Endometrial cavity appears grossly uninvolved by tumor.

Summary of sections: One longitudinal slice through posterior wall of uterus submitted inferior to superior with superior most slice bisected, submitted respectively in "3A" through "3D"; additional section of mass from posterior wall with vaginal resection margin, "3E"; one longitudinal slice through anterior wall, submitted inferior to superior, superior edge inked blue for reference, "3F" through "3H" respectively; anterior vaginal cuff, "3I"; left lateral parametrium, "3J"; right lateral parametrium, "3K"; additional section of mass with vaginal cuff at posterior wall, "3L".

Specimen "No. 4" labeled "Left Pelvic Lymph Nodes" consists of fibrofatty tissue measuring 7x5x1 cm. The specimen is submitted as: "4A", six possible nodes; "4B", three possible nodes; "4C", one possible node. (Dictated by [REDACTED])

FROZEN SECTION DIAGNOSIS

1FS) Benign lymph node section)

(Confirmed on paraffin

MICROSCOPIC:

Synoptic Summary for Cervical Carcinoma in Radical Hysterectomy

Changes of prior conization: Not identified

Size in largest dimension: 3 cm

How much of the circumference of the cervix is involved: 50%

[page 2 of 2]
Thickness of tumor and total thickness of the wall of cervix in the same region: 19 mm in an area where cervix is 2 cm in thickness (2L)

Lymphatic/vascular invasion: Present (3A)

In situ carcinoma: Not present

Distance to vaginal resection margin: 6 mm (slide 3E)

Right and left parametrium: Negative for carcinoma

Type of carcinoma and degree of differentiation: Squamous cell carcinoma, well differentiated

Right and left pelvic lymph nodes: 16 pelvic lymph nodes negative for carcinoma (6 right pelvic, 10 left pelvic nodes)

Incidental findings in other submitted tissues: Benign secretory endometrium

FINAL DIAGNOSIS:

Uterus: Radical Hysterectomy:

Invasive squamous cell carcinoma (well differentiated) without lymph node metastasis (please see synoptic for details)

This case was reviewed at our daily QA conference with agreement as to the above diagnosis.

19 blocks

As the staff pathologist, I have personally examined all slides and relevant information about this case and have discussed them with Dr. and arrived at the diagnosis that is recorded in my report.

Diagnostician:

Staff Pathologist

Electronically Signed

Source: NCI Genomic Data Commons file 07f02442-346c-4129-ab04-6225e00642d2 (TCGA-EK-A2RC.1FBD6F5F-52DB-4DA3-AB1D-BB81200A032B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).